EXCEPTIONAL_RESPONDERS case ER-AE8R — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b5faedc9-bdac-40e7-ac6d-9a0b00052786

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1961; Vital status: Alive.

Diagnoses (1)
1. Clear cell carcinoma: ICD-O-3 morphology code: 8310/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Classification of tumor: primary; Age at diagnosis: 49.4 years (18,031 days); Year of diagnosis: 2011; Prior malignancy: no; Days to last follow up: 1,203 days (3.3 years); Days to best overall response: 568 days (1.6 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Sunitinib Malate; Days to treatment start: 404 days (1.1 years); Days to treatment end: 761 days (2.1 years).

Follow-up (1 entry)
- Days to follow up: 1,203 days (3.3 years); Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 932 days (2.6 years); Days progression-free: 1,203 days (3.3 years).

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AE8R-NT1-A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AE8R-NT1-A-1-0-S1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-AE8R-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AE8R-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 30; Percent tumor nuclei: 40; Percent normal cells: 50; Percent necrosis: 5; Percent stromal cells: 15; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-AE8R-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-AE8R-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 50; Percent normal cells: 5; Percent necrosis: 25; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
